Somatic mutation profile of tumor specimen TCGA-A2-A0SV-01A (aliquot TCGA-A2-A0SV-01A-11D-A099-09) from TCGA case TCGA-A2-A0SV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.3 years (23,126 days).
Specimen TCGA-A2-A0SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c132854-804e-40cc-a6db-3252ebd928ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0SV-10A (Blood Derived Normal), aliquot TCGA-A2-A0SV-10A-01W-A097-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0c20a74-6cb9-4123-816e-a26baca93163

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 20, Silent 13, In Frame Del 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61249454; called by muse, mutect2, varscan2
- ATP9A | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV58763775; called by muse, mutect2, varscan2
- BRDT | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62863577; called by muse, mutect2, varscan2
- C19orf44 | c.193A>C p.K65Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV54168625; called by muse, mutect2, varscan2
- CEP76 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs946761094, COSV50865617; called by muse, mutect2, varscan2
- CIT | c.5006C>T p.S1669F | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55861703; called by muse, mutect2, varscan2
- CNKSR2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV99668123; called by muse, mutect2
- DYNC2H1 | c.6479A>G p.N2160S | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1305882915, COSV62087660; called by muse, mutect2, varscan2
- DYRK2 | c.1133G>T p.R378L (on ENST00000344096 / NM_006482.3; = p.R305L on NM_003583.4) | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59845139, COSV59845482; called by muse, mutect2, varscan2
- FAT2 | c.5269A>G p.M1757V | Missense Mutation (SNP) | VAF 111/158 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55814506; called by muse, mutect2, varscan2
- FAT3 | c.9313G>A p.A3105T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1377070763, COSV53081502, COSV53085452; called by muse, mutect2, varscan2
- FBN2 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52495935; called by muse, mutect2, varscan2
- GRM7 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100736150, COSV63133004; called by muse, mutect2
- HDAC9 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67768006, COSV67776035; called by muse, mutect2, varscan2
- ITGA2B | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1355327407, COSV52231403; called by muse, mutect2, varscan2
- KCNG4 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs544548852, COSV100376997; called by muse, mutect2
- KMT2C | c.4141A>G p.I1381V | Missense Mutation (SNP) | VAF 74/106 reads (70%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51344234; called by muse, mutect2, varscan2
- MOV10L1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs752711170, COSV53167220, COSV53167920; called by muse, mutect2, varscan2
- PHACTR1 | c.1250_1252del p.K417_V418delinsI | In Frame Del (DEL) | VAF 19/67 reads (28%) | catalogued as COSV60660483; called by mutect2, pindel, varscan2
- PRPS1L1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs370031024; called by muse, mutect2, varscan2
- SLC6A4 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55565335; called by muse, mutect2, varscan2
- SORBS2 | c.2413T>A p.C805S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV52992646; called by muse, mutect2, varscan2
- TP53 | c.336_344del p.F113_H115del | In Frame Del (DEL) | VAF 8/15 reads (53%) | catalogued as COSV52763335; called by mutect2, varscan2
- BTN2A1 | c.173dup p.N58Kfs*3 | Frame Shift Ins (INS) | VAF 94/302 reads (31%) | called by mutect2, pindel, varscan2
- CFTR | c.4148_4156del p.I1383_R1385del | In Frame Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.190_195del p.H64_Y65del | In Frame Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- AMBP | c.786C>T p.G262= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs374833274; called by muse, mutect2, varscan2
- AOC3 | c.2106C>T p.G702= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV57732752; called by muse, mutect2, varscan2
- DMRTA1 | c.1251T>A p.A417= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs913826524, COSV57923826; called by muse, mutect2, varscan2
- EFNB1 | c.804G>A p.R268= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV52661092; called by muse, mutect2, varscan2
- EPHB3 | c.2985T>C p.P995= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57804517; called by muse, mutect2
- FMO4 | c.558C>T p.R186= | Silent (SNP) | VAF 26/245 reads (11%) | catalogued as rs1053562450, COSV63000778; called by muse, mutect2, varscan2
- ITGA8 | c.2355G>A p.A785= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as rs145199076, COSV65225383; called by muse, mutect2, varscan2
- MORN5 | c.363C>T p.Y121= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as rs780115896, COSV65648538; called by muse, mutect2, varscan2
- OR51A2 | c.261C>T p.F87= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV66748154; called by muse, mutect2, varscan2
- OR52E4 | c.285C>T p.S95= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV57624040, COSV57624249; called by muse, mutect2, varscan2
- OTUD5 | c.843C>T p.N281= | Silent (SNP) | VAF 8/217 reads (4%) | catalogued as COSV99331826; called by muse, mutect2
- PCDHGB2 | c.849T>C p.N283= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV53907353; called by muse, mutect2, varscan2
- VKORC1 | c.189C>T p.F63= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1282308346, COSV54922918; called by muse, mutect2, varscan2
